Gene-level copy-number profile of tumor specimen TCGA-A2-A04X-01A from TCGA case TCGA-A2-A04X, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 34.6 years (12,642 days).
Specimen TCGA-A2-A04X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.456b1e0c-72a4-4850-b52b-8eecf5ecabd8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A04X-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/14b86d15-5d62-4761-b64e-5006dfd8d817

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,810; copy number 2: 46,161; copy number 3: 3,841; copy number 4: 148; copy number 5: 179; copy number 6: 117; copy number 7: 60; copy number 8: 28; copy number 9: 172; copy number 11: 62; copy number 12: 151; copy number 13: 55; copy number 15: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A04X-01A-21D-A036-01): tumor purity 0.59, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 859 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:145,738,868–145,977,811, 14 genes, copy number 8 (within-gene range 1–8): RNF115, POLR3C, NUDT17, PIAS3, MIR6736, ANKRD35, ITGA10, AC243547.1, PEX11B, RBM8A, GNRHR2, LIX1L-AS1, AC243547.3, LIX1L.
- chr1:147,445,579–149,556,361, 72 genes, copy number 5–7 (broad region; genes not listed).
- chr1:150,487,364–150,720,895, 17 genes, copy number 12: TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P.
- chr1:150,887,136–151,035,713, 10 genes, copy number 8 (within-gene range 1–8): CTXND2, CYCSP51, SETDB1, CERS2, AL590133.2, AL590133.1, ANXA9, MINDY1, PRUNE1, RNU6-884P.
- chr1:151,510,510–151,583,583, 6 genes, copy number 6 (within-gene range 3–6): CGN, AL365436.3, TUFT1, AL365436.2, MIR554, AL365436.1.
- chr1:151,700,058–152,776,728, 61 genes, copy number 6 (broad region; genes not listed).
- chr1:152,827,473–152,843,983, 2 genes, copy number 7: LCE1A, LCE6A.
- chr1:153,174,518–154,628,013, 96 genes, copy number 5–9 (within-gene range 1–9) (broad region; genes not listed).
- chr1:154,924,740–155,750,137, 62 genes, copy number 11 (broad region; genes not listed).
- chr1:159,466,321–159,483,376, 1 gene, copy number 6: LINC02819.
- chr1:160,537,073–162,599,842, 95 genes, copy number 9–12 (within-gene range 1–12) (broad region; genes not listed).
- chr1:165,476,838–166,452,632, 28 genes, copy number 6 (within-gene range 1–6): LRRC52-AS1, PRELID1P7, LRRC52, AL356441.2, AL356441.1, MGST3, ALDH9A1, Y_RNA, AL451074.3, AL451074.2, AL451074.1, AL451074.5, TMCO1, TMCO1-AS1, AL451074.4, UCK2, AL358115.1, MIR3658, AL606495.1, RPS3AP10, RNA5SP64, FAM78B, FAM78B-AS1, AL596087.3, MIR921, AL596087.2, AL596087.1, AL583804.1.
- chr17:39,063,313–39,977,768, 35 genes, copy number 15 (within-gene range 1–15): PLXDC1, AC091178.2, ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA.
- chr17:47,807,372–52,535,701, 198 genes, copy number 8–12 (within-gene range 4–12) (broad region; genes not listed).
- chr17:55,392,622–55,872,939, 8 genes, copy number 6: MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1.
- chr17:57,085,092–57,121,346, 1 gene, copy number 5 (within-gene range 3–5): AKAP1.
- chr17:57,196,081–61,485,110, 153 genes, copy number 5–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,810. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
